Somatic mutation profile of tumor specimen MMRF_2244_1_BM_CD138pos (aliquot MMRF_2244_1_BM_CD138pos_T1_KHS5U_L09552) from MMRF case MMRF_2244, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 51.0 years (18,636 days).
Specimen MMRF_2244_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7eb94524-ac5f-48b7-85d1-0aa6e905aaf6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2244_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2244_1_PB_Whole_C2_KHS5U_L09553; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b15b04ea-baf1-46d4-80f8-bad96234251e

The open-access MAF lists 101 somatic variants for this specimen: 37 protein-altering or splice-affecting, 17 silent, 47 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 32, Missense Mutation 32, Silent 17, Intron 8, 5'Flank 4, Frame Shift Del 4, 3'Flank 2, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AQP3 | c.556G>A p.V186I | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.01); catalogued as rs760141667, COSV53049138; called by muse, mutect2, varscan2
- ASCC3 | c.3844G>A p.V1282I | Missense Mutation (SNP) | VAF 15/173 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.3); catalogued as rs1317964873; called by muse, mutect2
- FGFRL1 | c.38C>T p.P13L | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as rs1165784717, COSV53256588; called by muse, mutect2, varscan2
- FZD2 | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 70/126 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.343); catalogued as COSV100190785; called by muse, mutect2, varscan2
- H2BC12 | c.189G>A p.M63I | Missense Mutation (SNP) | VAF 67/173 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.451); catalogued as COSV104418618; called by muse, mutect2, varscan2
- IGHV2-70 | c.296T>G p.V99G | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs755372451; called by muse, varscan2
- LOXHD1 | c.3157G>A p.D1053N | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.583); catalogued as COSV56064120; called by muse, mutect2, varscan2
- LRRTM4 | c.1048G>T p.V350F | Missense Mutation (SNP) | VAF 31/215 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV69139301; called by muse, mutect2, varscan2
- MMP17 | c.436C>G p.P146A | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV62181549; called by muse, mutect2, varscan2
- NPAT | c.674C>G p.P225R | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); catalogued as rs1167368965, COSV53717054; called by muse, mutect2, varscan2
- PHLDB1 | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 238/510 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61879412; called by muse, mutect2, varscan2
- RAPGEF6 | c.4771G>A p.E1591K | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.137); catalogued as rs747389311; called by muse, mutect2, varscan2
- RND3 | c.174G>C p.E58D | Missense Mutation (SNP) | VAF 84/168 reads (50%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.808); catalogued as COSV55725026; called by muse, mutect2, varscan2
- SPRTN | c.1297G>A p.D433N | Missense Mutation (SNP) | VAF 17/168 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.154); catalogued as COSV50480321; called by muse, mutect2, varscan2
- XDH | c.2891C>T p.T964I | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.424); catalogued as rs752757534; called by muse, mutect2
- ATRX | c.6142G>T p.D2048Y | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- BCL7A | c.70_87delinsATCGT p.A24Ifs*9 | Frame Shift Del (DEL) | VAF 19/64 reads (30%) | called by pindel, varscan2*
- CABIN1 | c.1954_1967del p.Q652Gfs*2 | Frame Shift Del (DEL) | VAF 13/106 reads (12%) | called by mutect2, pindel, varscan2
- COMT | c.327del p.S110Pfs*49 | Frame Shift Del (DEL) | VAF 8/56 reads (14%) | called by mutect2, pindel
- FAM149A | c.448G>A p.G150R | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- IGHV2-70D | c.142C>T p.L48F | Missense Mutation (SNP) | VAF 71/140 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.517); called by muse, varscan2
- KCNE4 | c.388C>T p.L130F | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2
- LRBA | c.1249A>T p.I417F | Missense Mutation (SNP) | VAF 38/216 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- MDK | c.119G>C p.W40S | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.435); called by muse, mutect2, varscan2
- MEP1A | c.1092G>T p.R364S | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- MMP27 | c.1050G>A p.M350I | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MYBPH | c.1367C>T p.A456V | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NAV3 | c.231A>T p.K77N | Missense Mutation (SNP) | VAF 4/75 reads (5%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.007); called by muse, mutect2
- NUSAP1 | c.159T>A p.N53K | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- PRKAA1 | c.1222C>T p.H408Y | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SLC5A3 | c.841G>A p.V281I | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SMC1A | c.1373A>G p.E458G | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2
- TCERG1 | c.2747T>A p.V916E | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- TENT5C | c.215dup p.N72Kfs*38 | Frame Shift Ins (INS) | VAF 31/121 reads (26%) | called by mutect2, pindel, varscan2
- VASH1 | c.146G>A p.G49E | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); called by muse, varscan2
- YTHDC2 | c.35del p.P12Rfs*25 | Frame Shift Del (DEL) | VAF 15/59 reads (25%) | called by mutect2, pindel, varscan2
- ZMYM2 | c.1915T>C p.C639R | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ANKRD30B | c.3783A>C p.S1261= | Silent (SNP) | VAF 20/136 reads (15%) | called by mutect2, varscan2
- GYG2 | c.465G>A p.A155= | Silent (SNP) | VAF 59/86 reads (69%) | catalogued as rs370610122, COSV58552326; called by muse, mutect2, varscan2
- IGHJ5 | c.42C>T p.V14= | Silent (SNP) | VAF 56/89 reads (63%) | catalogued as rs573414390; called by muse, varscan2
- IGHV2-70 | c.282C>T p.T94= | Silent (SNP) | VAF 38/96 reads (40%) | catalogued as rs368464634; called by muse, varscan2
- IGHV2-70 | c.264C>G p.L88= | Silent (SNP) | VAF 67/116 reads (58%) | catalogued as rs529380578; called by muse, varscan2
- IGHV2-70 | c.57C>A p.S19= | Silent (SNP) | VAF 40/117 reads (34%) | catalogued as rs554480066; called by muse, mutect2, varscan2
- IGHV2-70D | c.315C>T p.N105= | Silent (SNP) | VAF 37/77 reads (48%) | called by muse, varscan2
- IGLL5 | c.114G>A p.L38= | Silent (SNP) | VAF 24/24 reads (100%) | catalogued as rs556230331, COSV73249618, COSV73250730; called by muse, varscan2
- IGLL5 | c.132A>T p.A44= | Silent (SNP) | VAF 20/20 reads (100%) | catalogued as rs559053132, COSV73250410, COSV73251264; called by muse, varscan2
- IGLV3-1 | c.294T>C p.A98= | Silent (SNP) | VAF 46/146 reads (32%) | catalogued as rs546240484; called by muse, varscan2
- KAT2B | c.882C>T p.F294= | Silent (SNP) | VAF 9/62 reads (15%) | called by muse, mutect2, varscan2
- KDM6A | c.3321T>C p.P1107= | Silent (SNP) | VAF 22/33 reads (67%) | called by muse, mutect2, varscan2
- LRBA | c.1248C>A p.A416= | Silent (SNP) | VAF 39/221 reads (18%) | called by muse, mutect2, varscan2
- LRP1 | c.7447C>A p.R2483= | Silent (SNP) | VAF 97/200 reads (49%) | catalogued as COSV54516155; called by muse, mutect2, varscan2
- MARCHF10 | c.1206G>A p.S402= | Silent (SNP) | VAF 44/154 reads (29%) | catalogued as rs369884194; called by muse, mutect2, varscan2
- SPTBN4 | c.7110C>T p.D2370= | Silent (SNP) | VAF 8/58 reads (14%) | called by muse, varscan2
- TONSL | c.339C>T p.I113= | Silent (SNP) | VAF 86/204 reads (42%) | catalogued as rs528184833, COSV68047978; called by muse, mutect2, varscan2
- BCHE | c.*300A>C | 3'UTR (SNP) | VAF 108/216 reads (50%) | called by muse, mutect2, varscan2
- C8orf34 | c.1105+474G>C | Intron (SNP) | VAF 11/89 reads (12%) | called by muse, mutect2, varscan2
- CALN1 | c.*3969A>G | 3'UTR (SNP) | VAF 48/82 reads (59%) | called by muse, mutect2, varscan2
- CATSPER2 | c.1555+681G>C | Intron (SNP) | VAF 7/108 reads (6%) | called by muse, mutect2
- CCNB2 | c.-23C>T | 5'UTR (SNP) | VAF 40/265 reads (15%) | called by muse, mutect2, varscan2
- CNGA3 | c.*534A>C | 3'UTR (SNP) | VAF 27/52 reads (52%) | called by muse, mutect2, varscan2
- DBI | c.9+562C>T | Intron (SNP) | VAF 89/191 reads (47%) | catalogued as rs200535268; called by muse, mutect2, varscan2
- DCTN5 | c.*1412C>T | 3'UTR (SNP) | VAF 7/53 reads (13%) | called by muse, mutect2, varscan2
- DTX1 | chr12:113057627 A>G | 5'Flank (SNP) | VAF 5/10 reads (50%) | called by muse, mutect2
- FAM53B | c.*2630G>A | 3'UTR (SNP) | VAF 29/71 reads (41%) | catalogued as rs991777900; called by muse, mutect2, varscan2
- FAM71D | c.160-1582T>G | Intron (SNP) | VAF 26/53 reads (49%) | called by muse, mutect2, varscan2
- FIGN | c.*3152C>A | 3'UTR (SNP) | VAF 10/56 reads (18%) | called by muse, mutect2, varscan2
- GABRA1 | chr5:161899898 T>G | 3'Flank (SNP) | VAF 29/47 reads (62%) | called by muse, mutect2, varscan2
- HDAC4 | c.*3591G>C | 3'UTR (SNP) | VAF 16/28 reads (57%) | called by muse, mutect2, varscan2
- IGHJ6 | chr14:105863423 T>C | 5'Flank (SNP) | VAF 10/28 reads (36%) | catalogued as rs937738884; called by muse, varscan2
- LHX5 | c.*333C>G | 3'UTR (SNP) | VAF 4/30 reads (13%) | catalogued as rs1335349856; called by muse, mutect2
- LRAT | c.*987C>T | 3'UTR (SNP) | VAF 16/110 reads (15%) | called by muse, mutect2, varscan2
- MANF | c.223-20A>G | Intron (SNP) | VAF 26/53 reads (49%) | called by mutect2, varscan2
- MAPKAP1 | c.*955G>A | 3'UTR (SNP) | VAF 7/168 reads (4%) | called by muse, mutect2
- MITF | c.*2865C>T | 3'UTR (SNP) | VAF 17/96 reads (18%) | called by muse, mutect2, varscan2
- MSANTD4 | c.*300T>G | 3'UTR (SNP) | VAF 27/69 reads (39%) | called by muse, mutect2, varscan2
- NCAM2 | c.*3832T>C | 3'UTR (SNP) | VAF 7/47 reads (15%) | called by muse, mutect2, varscan2
- NCAM2 | c.*3926A>T | 3'UTR (SNP) | VAF 9/40 reads (23%) | called by muse, mutect2, varscan2
- NEU4 | chr2:241809351 G>T | 5'Flank (SNP) | VAF 8/151 reads (5%) | called by muse, mutect2
- NLGN2 | c.*1093C>T | 3'UTR (SNP) | VAF 6/122 reads (5%) | catalogued as rs954315938; called by muse, mutect2
- NRARP | c.*378C>A | 3'UTR (SNP) | VAF 24/114 reads (21%) | catalogued as rs867173923; called by muse, mutect2, varscan2
- OTOA | chr16:21760575 C>T | 3'Flank (SNP) | VAF 13/67 reads (19%) | called by muse, mutect2, varscan2
- PAX9 | c.*2853T>C | 3'UTR (SNP) | VAF 33/79 reads (42%) | called by muse, mutect2, varscan2
- PDE1C | c.1892-13105G>T | Intron (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2, varscan2
- POLR1F | c.*2585G>A | 3'UTR (SNP) | VAF 18/95 reads (19%) | called by muse, mutect2, varscan2
- RADX | c.*436C>T | 3'UTR (SNP) | VAF 7/51 reads (14%) | called by muse, mutect2, varscan2
- RGP1 | c.*3199C>T | 3'UTR (SNP) | VAF 44/182 reads (24%) | called by muse, mutect2, varscan2
- RYBP | c.*2742C>T | 3'UTR (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- SLAIN2 | c.*931C>A | 3'UTR (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- SLAIN2 | c.*933T>G | 3'UTR (SNP) | VAF 6/95 reads (6%) | called by muse, mutect2
- SRD5A1 | c.*155C>T | 3'UTR (SNP) | VAF 67/150 reads (45%) | called by muse, mutect2, varscan2
- SSR1 | c.544-17T>G | Intron (SNP) | VAF 13/125 reads (10%) | called by muse, mutect2, varscan2
- SYBU | chr8:109646886 C>T | 5'Flank (SNP) | VAF 5/86 reads (6%) | called by muse, mutect2
- SYT2 | c.*1503G>A | 3'UTR (SNP) | VAF 5/101 reads (5%) | called by muse, mutect2
- TRIM33 | c.*580T>C | 3'UTR (SNP) | VAF 58/115 reads (50%) | catalogued as rs113976766; called by muse, mutect2, varscan2
- TRPS1 | c.*761A>G | 3'UTR (SNP) | VAF 17/106 reads (16%) | called by muse, mutect2, varscan2
- URB1 | c.*2754G>A | 3'UTR (SNP) | VAF 38/75 reads (51%) | called by muse, mutect2, varscan2
- VTA1 | c.*1142G>A | 3'UTR (SNP) | VAF 11/79 reads (14%) | called by muse, mutect2, varscan2
- VXN | c.440+69A>T | Intron (SNP) | VAF 16/85 reads (19%) | called by muse, mutect2, varscan2
- ZNF385B | c.*1026dup | 3'UTR (INS) | VAF 18/49 reads (37%) | catalogued as rs1190080358; called by mutect2, varscan2
- ZNF747 | c.*2513G>A | 3'UTR (SNP) | VAF 10/86 reads (12%) | called by muse, mutect2, varscan2
- ZNF860 | c.*521G>A | 3'UTR (SNP) | VAF 11/89 reads (12%) | called by muse, mutect2, varscan2
